Gene-level copy-number profile of tumor specimen TCGA-D6-A6EO-01A from TCGA case TCGA-D6-A6EO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 44.3 years (16,185 days).
Specimen TCGA-D6-A6EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.7b398212-6bc6-40ab-adfb-2fd2d30ff091.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-A6EO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ddaffe7-4ff2-4bc7-9393-b8d2dbdb5b16

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 12,282; copy number 2: 41,486; copy number 3: 4,483; copy number 4: 736; copy number 5: 443; copy number 6: 114; copy number 7: 56; copy number 8: 32; copy number 10: 70; copy number 12: 6; copy number 15: 2; copy number 19: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-A6EO-01A-11D-A31K-01): tumor purity 0.71, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,330,120–153,460,651, 11 genes: PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7.
- chr3:74,262,568–84,051,419, 77 genes (within-gene range 0–1) (broad region; genes not listed).
- chr8:27,311,482–27,589,073, 5 genes (within-gene range 0–2): PTK2B, MIR6842, CHRNA2, EPHX2, GULOP.
- chr18:47,285,725–47,594,550, 4 genes (within-gene range 0–7): MIR4527HG, MIR4527, AC102797.2, AC102797.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 734 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:147,025,914–147,344,717, 3 genes, copy number 5: AC092435.4, AC097450.1, MIR548G.
- chr4:159,665,833–160,818,869, 4 genes, copy number 5: LINC02233, AC093853.1, LINC02477, RPS14P7.
- chr7:91,692,008–96,110,322, 79 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr7:96,120,220–113,494,870, 389 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:50,908,672–54,633,414, 70 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr18:1,509,022–6,915,716, 97 genes, copy number 6–10 (within-gene range 2–14) (broad region; genes not listed).
- chr18:38,655,209–47,282,939, 92 genes, copy number 6–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,895. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
